Somatic mutation profile of tumor specimen C3L-02546-03 (aliquot CPT0112650009) from CPTAC case C3L-02546, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 74.6 years (27,236 days).
Specimen C3L-02546-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58ef79f6-7cef-41a5-8737-e8a858cca196.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02546-31 (Blood Derived Normal), aliquot CPT0115180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5af2f8ed-7803-44ba-bb0e-be2497058d22

The open-access MAF lists 268 somatic variants for this specimen: 188 protein-altering or splice-affecting, 58 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 58, Intron 15, Nonsense Mutation 9, Splice Site 7, Splice Region 3, Frame Shift Del 3, RNA 3, 5'UTR 2, In Frame Ins 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.802-2A>G p.X268_splice | Splice Site (SNP) | VAF 10/86 reads (12%) | hotspot (GDC flag); catalogued as rs587782455, CS1513175, COSV64297401, COSV64297403, COSV64301847, COSV64304652; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 74/358 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AMOT | c.2884T>G p.S962A (on ENST00000371959 / NM_001113490.1; = p.S553A on NM_133265.3) | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs200613321; called by mutect2, varscan2
- ARHGAP33 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as rs759423493, COSV99140036; called by muse, mutect2
- ARHGAP36 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs974805626, COSV52266263, COSV52274371; called by muse, mutect2, varscan2
- BLOC1S3 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 66/441 reads (15%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.969); catalogued as rs915791995; called by muse, mutect2, varscan2
- BRINP3 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 66/363 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV66542804; called by muse, mutect2, varscan2
- C9orf131 | c.2794A>G p.R932G | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV100397971; called by muse, mutect2, varscan2
- CA5A | c.411C>A p.N137K | Missense Mutation (SNP) | VAF 29/351 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs766745985, COSV59242942; called by muse, mutect2
- CACNA2D1 | c.3086G>A p.R1029Q (on ENST00000356253 / NM_001366867.1; = p.R1017Q on NM_000722.4) | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs79216498; called by muse, mutect2
- CADPS2 | c.2759A>G p.N920S | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.45); catalogued as rs772722168; called by muse, mutect2, varscan2
- CCT2 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs1345399957; called by muse, mutect2
- CNTNAP5 | c.3155T>A p.L1052H | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV70479290, COSV70491845; called by muse, mutect2
- COG5 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs751598750; called by muse, mutect2, varscan2
- COL27A1 | c.4673A>G p.Q1558R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.372); catalogued as rs747205748; called by muse, mutect2
- CSMD2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | catalogued as rs897426989; called by muse, mutect2, varscan2
- CSMD3 | c.10756G>C p.D3586H (on ENST00000297405 / NM_001363185.1; = p.D3417H on NM_052900.3) | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV99850199; called by muse, mutect2, varscan2
- DHX32 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV52940109; called by muse, mutect2, varscan2
- DIRAS1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs770364194; called by muse, mutect2, varscan2
- DNAAF2 | c.1453A>T p.S485C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs369837291; called by muse, mutect2, varscan2
- DOCK9 | c.241C>G p.Q81E (on ENST00000376460 / NM_001366676.2; = p.Q82E on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs866581683; called by muse, mutect2
- EMC1 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.813); catalogued as rs527601179; called by muse, mutect2, varscan2
- GALNT17 | c.860G>C p.R287P | Missense Mutation (SNP) | VAF 65/606 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.949); catalogued as COSV61183056; called by muse, varscan2
- GSTA2 | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs762917334; called by muse, mutect2, varscan2
- HERC2 | c.13108G>A p.E4370K | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.432); catalogued as COSV99874899; called by muse, mutect2
- HJURP | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs899944289; called by muse, mutect2
- IMPA1 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1238506691, COSV56272940; called by muse, mutect2, varscan2
- KCNH1 | c.1718G>T p.R573L (on ENST00000271751 / NM_172362.3; = p.R546L on NM_002238.4) | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1298982867, COSV99660601; called by muse, mutect2, varscan2
- KIF21B | c.4438G>A p.V1480I (on ENST00000422435 / NM_001252100.2; = p.V1467I on NM_017596.4) | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.863); catalogued as rs1208206673, COSV100145473; called by muse, mutect2, varscan2
- KLK15 | c.374C>A p.A125E | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV56826190, COSV56827776; called by muse, varscan2
- KRTAP10-3 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100552310, COSV59959098; called by muse, mutect2
- MANBA | c.1513G>A p.E505K (on ENST00000642252; = p.E459K on NM_005908.4) | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764135589; called by muse, mutect2
- MAP1A | c.7498C>T p.P2500S | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299644808; called by muse, mutect2
- MLXIPL | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1554603048; called by muse, mutect2
- MMP12 | c.787+1G>T p.X263_splice | Splice Site (SNP) | VAF 12/78 reads (15%) | catalogued as COSV58259954; called by muse, mutect2, varscan2
- MZT2B | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1294945187; called by muse, mutect2
- NCAN | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs779909748, COSV53053588; called by muse, mutect2, varscan2
- NCAN | c.2254G>T p.G752C | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs982235526; called by muse, mutect2, varscan2
- NCOR2 | c.5546C>T p.A1849V | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV62301810; called by muse, mutect2, varscan2
- NDUFA6 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 28/383 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs758833609, COSV58938398; called by muse, mutect2
- NETO1 | c.221C>A p.A74D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100199686; called by muse, mutect2, varscan2
- NLRP3 | c.1108G>A p.G370S | Missense Mutation (SNP) | VAF 25/483 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100275639; called by muse, mutect2
- NOL4 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52336704, COSV52341281; called by mutect2, varscan2
- NPY1R | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV56715994; called by muse, mutect2
- NUTM1 | c.1936C>A p.L646M | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV100149163; called by muse, mutect2, varscan2
- OR1C1 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV101376160, COSV68716034; called by muse, mutect2
- OR4N2 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 30/704 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175544692, COSV60053901; called by muse, mutect2
- OR51D1 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as rs1235094748, COSV62914697; called by muse, mutect2, varscan2
- OR6K2 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.595); catalogued as rs972986620, COSV62743305; called by muse, mutect2
- OR6S1 | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs775459797; called by muse, mutect2, varscan2
- OTOGL | c.1793A>G p.D598G (on ENST00000547103; = p.D589G on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs1441624628; called by muse, mutect2, varscan2
- PATJ | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs767060973; called by muse, mutect2
- PCDHGB6 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 89/482 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV99531762; called by muse, mutect2, varscan2
- PHF14 | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV68856662; called by muse, mutect2, varscan2
- PLCL2 | c.1753G>T p.D585Y (on ENST00000615277 / NM_001144382.2; = p.D459Y on NM_015184.5) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101196559; called by muse, mutect2, varscan2
- POU4F3 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 62/367 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100046920; called by muse, mutect2, varscan2
- POU6F1 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.12); catalogued as rs1234103309; called by muse, mutect2, varscan2
- PRRG3 | c.606G>C p.E202D | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.152); catalogued as COSV100948636; called by muse, mutect2, varscan2
- RAC3 | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs377254852; called by muse, mutect2
- ROR1 | c.1173C>T p.C391= | Splice Region (SNP) | VAF 16/156 reads (10%) | catalogued as rs763495095, COSV64286685, COSV64289643; called by muse, mutect2
- RYR2 | c.2291del p.P764Qfs*35 | Frame Shift Del (DEL) | VAF 13/116 reads (11%) | catalogued as COSV63662190; called by pindel, varscan2
- SACS | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461096954, COSV66538129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAI | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as COSV100332525; called by muse, mutect2, varscan2
- SHCBP1 | c.974G>C p.R325P | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57647889; called by muse, mutect2, varscan2
- SLC22A11 | c.1058+5G>A | Splice Region (SNP) | VAF 33/345 reads (10%) | catalogued as rs201314585; called by muse, mutect2
- SLC7A9 | c.547G>C p.A183P | Missense Mutation (SNP) | VAF 56/478 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99195359; called by muse, mutect2
- SUPT16H | c.2940G>T p.L980F | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV52846231; called by muse, mutect2
- SYT3 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs768869008, COSV100144380; called by muse, mutect2
- TFPI2 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55989748; called by muse, mutect2, varscan2
- TRIM43 | c.408C>A p.H136Q | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV55528490, COSV55529145; called by muse, mutect2, varscan2
- TRIO | c.7609G>A p.V2537M | Missense Mutation (SNP) | VAF 128/393 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100702665; called by muse, mutect2, varscan2
- TUBB4A | c.484del p.R162Afs*3 | Frame Shift Del (DEL) | VAF 83/565 reads (15%) | catalogued as COSV51163156; called by mutect2, pindel, varscan2
- USP13 | c.806-1G>T p.X269_splice | Splice Site (SNP) | VAF 61/140 reads (44%) | catalogued as COSV55863418; called by muse, mutect2, varscan2
- ZBTB24 | c.1666G>T p.V556L | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57781577; called by muse, mutect2, varscan2
- ZNF672 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 58/532 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.765); catalogued as rs368647505; called by muse, varscan2
- ZNF695 | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1331087319; called by muse, mutect2, varscan2
- ZNF716 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV70782130; called by muse, mutect2
- A1CF | c.988T>C p.S330P | Missense Mutation (SNP) | VAF 82/438 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- A2M | c.1492C>T p.L498= | Splice Region (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- ABCA13 | c.13943C>A p.P4648H | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACSM2A | c.243G>A p.W81* (on ENST00000219054; = p.W2* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 30/528 reads (6%) | called by muse, mutect2
- ADGRG7 | c.731C>A p.S244Y | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ANKRD11 | c.6755G>T p.G2252V | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD65 | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2
- ARMC3 | c.1219C>A p.L407M | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARMC4 | c.1698A>T p.K566N | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2
- ATP13A1 | c.2422G>C p.A808P | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- BCL11B | c.2347G>C p.G783R (on ENST00000357195 / NM_001282237.2; = p.G712R on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/444 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- BRSK1 | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- C19orf57 | c.746G>T p.R249I | Missense Mutation (SNP) | VAF 80/404 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- C1orf43 | c.515G>T p.G172V (on ENST00000368521 / NM_001297718.2; = p.G138V on NM_015449.4) | Missense Mutation (SNP) | VAF 24/337 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- C1orf94 | c.1364C>A p.T455N (on ENST00000488417 / NM_001134734.2; = p.T265N on NM_032884.5) | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- C2orf78 | c.2356C>A p.P786T | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.191); called by muse, mutect2
- C2orf78 | c.2357C>A p.P786Q | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- CACNG8 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); called by muse, varscan2
- CCDC190 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- CDC42BPA | c.355-1G>A p.X119_splice | Splice Site (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- CLASP2 | c.2005G>T p.G669C | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- CLDN15 | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 67/329 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COG5 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPSF6 | c.105T>A p.D35E | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CSMD2 | c.452A>G p.Q151R | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.545); called by muse, mutect2
- DCC | c.1328G>T p.R443L | Missense Mutation (SNP) | VAF 50/594 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DEFB112 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DGAT1 | c.640G>T p.V214F | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- DIRAS1 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DMRTC2 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 91/651 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DNAH7 | c.6504G>C p.L2168F | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DPP4 | c.1954G>C p.A652P | Missense Mutation (SNP) | VAF 29/380 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DPP6 | c.1545C>G p.Y515* (on ENST00000377770 / NM_001364500.2; = p.Y453* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2
- DSCAML1 | c.674C>A p.T225K (on ENST00000321322; = p.T165K on NM_020693.4) | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- DUSP15 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EBF2 | c.897T>A p.H299Q | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ERF | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ERICH3 | c.4469G>T p.S1490I | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- EYS | c.6737C>A p.P2246H | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAM205A | c.849C>A p.H283Q | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); called by muse, mutect2
- FANK1 | c.608G>T p.W203L | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXF2 | c.1076G>T p.S359I | Missense Mutation (SNP) | VAF 31/333 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.068); called by muse, mutect2
- FRMD1 | c.157C>A p.H53N | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- GFUS | c.814del p.D272Ifs*18 | Frame Shift Del (DEL) | VAF 53/373 reads (14%) | called by mutect2, pindel, varscan2
- GLG1 | c.1522G>C p.E508Q | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.511); called by muse, mutect2
- GLIPR1L2 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GOLGA6L2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HCN2 | c.2605_2619del p.P869_G873del | In Frame Del (DEL) | VAF 19/172 reads (11%) | called by mutect2, pindel
- HHIP | c.1795C>A p.Q599K | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- HMCN2 | c.4870A>G p.T1624A | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, varscan2
- IGLV7-43 | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 65/299 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- JRK | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- KIR3DL2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- KIRREL2 | c.1154G>T p.R385L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- KIRREL2 | c.1973G>T p.R658M | Missense Mutation (SNP) | VAF 83/426 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- LAMB4 | c.745C>A p.L249I | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2
- LCOR | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.099); called by muse, mutect2
- LRRC8A | c.2110A>G p.I704V | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MAGEE1 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 97/211 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MDGA2 | c.2656A>T p.S886C (on ENST00000399232 / NM_001113498.2; = p.S588C on NM_182830.4) | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MOGAT3 | c.865A>T p.T289S | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); called by muse, mutect2
- MUC16 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); called by muse, mutect2
- MYH2 | c.421A>T p.T141S | Missense Mutation (SNP) | VAF 106/546 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH7 | c.5272G>C p.A1758P | Missense Mutation (SNP) | VAF 58/812 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NBPF6 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by mutect2, varscan2
- NEB | c.4275G>T p.R1425S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NLRC5 | c.2826C>G p.F942L | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NPAS3 | c.493C>A p.L165I (on ENST00000356141 / NM_001164749.2; = p.L133I on NM_022123.3) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- NPY1R | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- OLFM1 | c.892T>A p.W298R (on ENST00000371793 / NM_001282611.2; = p.W280R on NM_014279.5) | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OR2B11 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- OR2C3 | c.837C>A p.Y279* | Nonsense Mutation (SNP) | VAF 84/499 reads (17%) | called by muse, mutect2, varscan2
- OR5R1 | c.919A>G p.K307E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by mutect2, varscan2
- PBX3 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PHF21A | c.1614G>C p.K538N (on ENST00000418153 / NM_001101802.3; = p.K492N on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PIKFYVE | c.4194C>A p.F1398L | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- PNPLA8 | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- POTEE | c.2180C>A p.P727H | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- PRAG1 | c.1333G>T p.V445L | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.03); called by muse, mutect2
- PRAMEF15 | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 46/409 reads (11%) | called by muse, mutect2, varscan2
- PRSS55 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 20/183 reads (11%) | called by muse, mutect2
- PTDSS1 | c.1174-1G>T p.X392_splice | Splice Site (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- PTDSS1 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.057); called by muse, mutect2
- PTPRN | c.1234C>G p.P412A | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PXDN | c.1322A>G p.D441G | Missense Mutation (SNP) | VAF 23/357 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); called by muse, mutect2
- RCN3 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- RIF1 | c.4481_4498dup p.T1499_E1500insGANAET | In Frame Ins (INS) | VAF 11/49 reads (22%) | called by mutect2, varscan2*
- ROS1 | c.6435-21_6450del p.X2145_splice | Splice Site (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- RPS4X | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- RYR2 | c.13004C>A p.P4335Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA3A | c.1619C>G p.S540C | Missense Mutation (SNP) | VAF 27/285 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.345); called by muse, mutect2
- SLC35G4 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SLC9C1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SUCNR1 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.005); called by muse, mutect2
- TLN2 | c.2260G>T p.V754F | Missense Mutation (SNP) | VAF 54/506 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- TMEM43 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOPAZ1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TPRX1 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TPRX1 | c.885C>A p.S295R | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- TPTE2 | c.771T>A p.H257Q (on ENST00000400230 / NM_199254.2; = p.H180Q on NM_130785.3) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- TRIM64C | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 32/454 reads (7%) | called by muse, mutect2
- TTN | c.72501T>A p.S24167R (on ENST00000591111; = p.S16743R on NM_003319.4) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TTN | c.52691G>T p.W17564L (on ENST00000591111; = p.W10140L on NM_003319.4) | Missense Mutation (SNP) | VAF 40/498 reads (8%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- UTRN | c.8921-2A>T p.X2974_splice | Splice Site (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
- VPS13D | c.8501A>T p.K2834I | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDFY4 | c.6437C>T p.S2146F | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- WDR62 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 64/873 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF160 | c.2125G>T p.E709* | Nonsense Mutation (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- ZNF610 | c.822C>G p.N274K | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.146); called by muse, mutect2
- ZNF709 | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ZNF729 | c.662C>G p.S221* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- ADAMTS10 | c.2025C>T p.G675= | Silent (SNP) | VAF 60/602 reads (10%) | catalogued as rs578073783; called by muse, mutect2
- ANKRD11 | c.6756G>T p.G2252= | Silent (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- ARMC3 | c.1218C>A p.L406= | Silent (SNP) | VAF 28/300 reads (9%) | called by muse, mutect2
- ARMH4 | c.873G>T p.L291= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV99958283; called by muse, mutect2, varscan2
- ATG9B | c.1977C>T p.F659= | Silent (SNP) | VAF 21/275 reads (8%) | called by muse, mutect2
- ATP6V0D2 | c.120G>A p.E40= | Silent (SNP) | VAF 51/276 reads (18%) | catalogued as COSV99572047; called by muse, varscan2
- BCKDHB | c.762A>G p.E254= | Silent (SNP) | VAF 57/281 reads (20%) | called by muse, mutect2, varscan2
- C20orf203 | c.432G>T p.T144= | Silent (SNP) | VAF 62/353 reads (18%) | catalogued as COSV62531536; called by muse, mutect2, varscan2
- CDKL1 | c.783C>G p.A261= | Silent (SNP) | VAF 24/219 reads (11%) | called by muse, mutect2, varscan2
- CDKN3 | c.360T>C p.C120= | Silent (SNP) | VAF 35/303 reads (12%) | called by muse, mutect2, varscan2
- CELF2 | c.81A>G p.G27= (on ENST00000416382 / NM_001025077.3; = p.G34= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 48/199 reads (24%) | called by muse, mutect2, varscan2
- CFH | c.3162A>T p.V1054= | Silent (SNP) | VAF 54/352 reads (15%) | called by muse, mutect2, varscan2
- COL27A1 | c.4671C>T p.I1557= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2
- CUBN | c.8166A>G p.P2722= | Silent (SNP) | VAF 43/537 reads (8%) | catalogued as rs1315612892; called by muse, mutect2
- EEF1AKNMT | c.318G>A p.T106= (on ENST00000361735 / NM_015935.5; = p.T20= on NM_014955.3) | Silent (SNP) | VAF 39/253 reads (15%) | catalogued as rs201273694, COSV62282516; called by muse, mutect2, varscan2
- FAM240C | c.69C>A p.G23= | Silent (SNP) | VAF 27/212 reads (13%) | catalogued as rs1257614498; called by muse, mutect2, varscan2
- FOXP3 | c.912C>T p.S304= | Silent (SNP) | VAF 38/184 reads (21%) | called by muse, mutect2, varscan2
- GJA10 | c.444T>C p.P148= | Silent (SNP) | VAF 17/129 reads (13%) | called by muse, mutect2, varscan2
- GK3P | c.393A>T p.P131= | Silent (SNP) | VAF 34/296 reads (11%) | called by muse, mutect2, varscan2
- GLI2 | c.3300G>T p.V1100= (on ENST00000361492 / NM_001374353.1; = p.V1117= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 93/813 reads (11%) | catalogued as COSV58040022; called by muse, mutect2, varscan2
- GORASP2 | c.966C>G p.L322= | Silent (SNP) | VAF 40/520 reads (8%) | called by muse, mutect2
- GRIN2C | c.1245C>T p.I415= | Silent (SNP) | VAF 79/721 reads (11%) | catalogued as rs768674628, COSV53111599; called by muse, mutect2, varscan2
- HTR7 | c.1344G>C p.P448= | Silent (SNP) | VAF 50/326 reads (15%) | catalogued as COSV99518781; called by muse, mutect2, varscan2
- INHBB | c.1041C>T p.A347= | Silent (SNP) | VAF 71/330 reads (22%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1020C>A p.I340= | Silent (SNP) | VAF 96/534 reads (18%) | catalogued as COSV60437407; called by muse, mutect2, varscan2
- KLK15 | c.294C>T p.Y98= | Silent (SNP) | VAF 45/369 reads (12%) | catalogued as rs981385274, COSV56827447; called by muse, varscan2
- KREMEN1 | c.270C>T p.D90= (on ENST00000407188; = p.D92= on NM_032045.5) | Silent (SNP) | VAF 38/466 reads (8%) | catalogued as rs763716781, COSV59912519; called by muse, mutect2
- MAP3K10 | c.813G>A p.A271= | Silent (SNP) | VAF 19/250 reads (8%) | catalogued as rs374027709, COSV99454237; called by muse, mutect2
- MDGA2 | c.1470G>A p.L490= (on ENST00000399232 / NM_001113498.2; = p.L192= on NM_182830.4) | Silent (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- MYH7 | c.2076G>A p.Q692= | Silent (SNP) | VAF 41/407 reads (10%) | called by muse, mutect2, varscan2
- NPHS2 | c.885A>G p.A295= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as rs146940071; called by muse, mutect2, varscan2
- NPTX2 | c.309C>T p.R103= | Silent (SNP) | VAF 57/237 reads (24%) | called by muse, mutect2, varscan2
- NRXN2 | c.2799G>T p.T933= | Silent (SNP) | VAF 49/184 reads (27%) | catalogued as rs1218578440; called by muse, mutect2, varscan2
- NRXN3 | c.1602G>A p.Q534= (on ENST00000335750 / NM_001330195.2; = p.Q161= on NM_004796.6) | Silent (SNP) | VAF 34/224 reads (15%) | called by muse, mutect2, varscan2
- NWD1 | c.1449C>T p.L483= | Silent (SNP) | VAF 25/242 reads (10%) | catalogued as rs756026611; called by muse, mutect2, varscan2
- OR14J1 | c.138C>A p.I46= | Silent (SNP) | VAF 47/341 reads (14%) | called by muse, mutect2, varscan2
- OR51A2 | c.756C>T p.F252= | Silent (SNP) | VAF 30/470 reads (6%) | called by muse, mutect2
- PARVB | c.318C>T p.I106= | Silent (SNP) | VAF 72/556 reads (13%) | catalogued as COSV58692417; called by muse, mutect2, varscan2
- PEPD | c.498C>T p.I166= | Silent (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- PKN1 | c.657G>A p.R219= | Silent (SNP) | VAF 39/343 reads (11%) | called by muse, mutect2, varscan2
- PTPRN | c.102C>T p.A34= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as COSV55347417; called by muse, mutect2
- RNASEH2A | c.285G>T p.V95= | Silent (SNP) | VAF 74/854 reads (9%) | catalogued as rs374650162; called by muse, mutect2
- RSPH6A | c.1335T>C p.T445= | Silent (SNP) | VAF 71/471 reads (15%) | called by muse, mutect2, varscan2
- SHH | c.60G>A p.S20= | Silent (SNP) | VAF 29/278 reads (10%) | catalogued as rs374343495; called by muse, mutect2, varscan2
- SND1 | c.2580G>A p.L860= | Silent (SNP) | VAF 34/385 reads (9%) | called by muse, mutect2
- SPICE1 | c.2286A>T p.P762= | Silent (SNP) | VAF 27/153 reads (18%) | called by muse, mutect2, varscan2
- THSD1 | c.1581G>T p.L527= | Silent (SNP) | VAF 51/263 reads (19%) | catalogued as COSV51628100; called by muse, mutect2, varscan2
- TMEM176B | c.627G>T p.L209= | Silent (SNP) | VAF 34/262 reads (13%) | catalogued as COSV58440226; called by muse, mutect2, varscan2
- TRIM13 | c.1107T>G p.V369= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- TTC34 | c.1776G>A p.R592= | Silent (SNP) | VAF 19/145 reads (13%) | called by muse, mutect2, varscan2
- TTC7A | c.537A>G p.L179= | Silent (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- TTN | c.57099C>T p.N19033= (on ENST00000591111; = p.N11609= on NM_003319.4) | Silent (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- UBN2 | c.2454C>A p.P818= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as COSV56035517; called by muse, mutect2
- UNC13A | c.822T>A p.S274= | Silent (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- USP34 | c.4431G>T p.V1477= | Silent (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- ZFAT | c.510G>A p.S170= | Silent (SNP) | VAF 21/322 reads (7%) | catalogued as rs770442363, COSV64750325; called by muse, mutect2
- ZNF74 | c.1311G>T p.T437= | Silent (SNP) | VAF 49/269 reads (18%) | called by muse, mutect2, varscan2
- ZNF804A | c.759C>A p.V253= | Silent (SNP) | VAF 23/127 reads (18%) | called by muse, mutect2, varscan2
- AC140125.2 | n.544G>C | RNA (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- AGK | c.141+124A>G | Intron (SNP) | VAF 47/230 reads (20%) | catalogued as rs1198471460; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840319 C>T | 5'Flank (SNP) | VAF 48/712 reads (7%) | catalogued as COSV100005821; called by muse, mutect2
- ARHGAP33 | c.502-335G>C | Intron (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.502-237G>A | Intron (SNP) | VAF 16/127 reads (13%) | called by muse, mutect2, varscan2
- BSG | c.416-399G>A | Intron (SNP) | VAF 50/448 reads (11%) | catalogued as rs1398512898; called by muse, mutect2, varscan2
- CRISP2 | c.515+150C>G | Intron (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- DAAM2 | c.1845+49A>T | Intron (SNP) | VAF 36/295 reads (12%) | called by muse, mutect2, varscan2
- DDX42 | c.726+37G>A | Intron (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- EPHB6 | c.1919-83C>T | Intron (SNP) | VAF 78/349 reads (22%) | called by muse, mutect2, varscan2
- FAM126A | c.-212G>A | 5'UTR (SNP) | VAF 58/330 reads (18%) | called by muse, mutect2, varscan2
- GVINP1 | n.5438G>A | RNA (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- IARS2 | c.1640+3696A>G | Intron (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- LDB2 | c.892-244T>A | Intron (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- LTO1 | c.50+22G>T | Intron (SNP) | VAF 44/147 reads (30%) | called by muse, mutect2, varscan2
- MATR3 | c.*956A>G | 3'UTR (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- SMAP1 | c.-10C>G | 5'UTR (SNP) | VAF 48/407 reads (12%) | catalogued as rs111809876; called by muse, mutect2, varscan2
- SPATA31C2 | n.2090C>A | RNA (SNP) | VAF 135/781 reads (17%) | called by muse, mutect2, varscan2
- TRPM4 | c.3329-50G>T | Intron (SNP) | VAF 49/231 reads (21%) | called by muse, mutect2, varscan2
- WNT8A | c.68+10T>C | Intron (SNP) | VAF 37/238 reads (16%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4593T>C | Intron (SNP) | VAF 61/489 reads (12%) | called by muse, mutect2, varscan2
- ZFAT | c.2475+590C>T | Intron (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
